Somatic mutation profile of tumor specimen e7b656bf-3c34-4ba1-bdf3-c7eefe (aliquot e7b656bf-3c34-4ba1-bdf3-c7eefe_D6) from CPTAC case 17OV025, project CPTAC-2 (Retroperitoneum and peritoneum — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Peritoneum, NOS; FIGO stage: Stage IIIA.
Specimen e7b656bf-3c34-4ba1-bdf3-c7eefe: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34b48aa2-f331-41ca-9379-47bc7ea166c1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 05256b36-6dfa-4f41-b13b-df0a38 (Blood Derived Normal), aliquot 05256b36-6dfa-4f41-b13b-df0a38_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/121827a8-0dbf-43e4-af09-367f34fa6741

The open-access MAF lists 290 somatic variants for this specimen: 200 protein-altering or splice-affecting, 52 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 159, Silent 52, Intron 25, Frame Shift Del 16, Nonsense Mutation 7, Splice Site 7, 5'Flank 6, In Frame Del 5, Splice Region 4, 5'UTR 3, Translation Start Site 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK2 | c.1976C>A p.T659K | Missense Mutation (SNP) | VAF 102/419 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1333180918; called by muse, mutect2, varscan2
- AOC1 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 141/600 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1368890538, COSV62867430; called by mutect2, varscan2
- CCDC107 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 116/791 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV58397676; called by muse, mutect2, varscan2
- CCNT1 | c.856A>G p.M286V | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.25); catalogued as rs1182795541; called by muse, mutect2, varscan2
- CDH8 | c.1383del p.W461Cfs*4 | Frame Shift Del (DEL) | VAF 26/108 reads (24%) | catalogued as COSV54892585; called by mutect2, pindel, varscan2
- CGAS | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.035); catalogued as rs1406989312; called by muse, mutect2, varscan2
- CLCA2 | c.2319A>C p.E773D | Missense Mutation (SNP) | VAF 47/236 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs753904651; called by muse, mutect2, varscan2
- DLGAP3 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 132/591 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs147968723, COSV52394894; called by muse, mutect2, varscan2
- DMBT1 | c.5573G>T p.C1858F (on ENST00000338354 / NM_001377530.1; = p.C1101F on NM_004406.3) | Missense Mutation (SNP) | VAF 165/288 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs772251223; called by muse, mutect2, varscan2
- DSCAM | c.827C>T p.T276M | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.88); catalogued as rs752670424, COSV68022860; called by muse, mutect2, varscan2
- DSG3 | c.2439G>T p.L813F | Missense Mutation (SNP) | VAF 43/308 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755575083; called by muse, mutect2, varscan2
- FAAP100 | c.1729C>T p.R577W | Missense Mutation (SNP) | VAF 86/430 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.406); catalogued as rs781730251; called by muse, mutect2, varscan2
- FAM135B | c.2156G>T p.R719L | Missense Mutation (SNP) | VAF 185/792 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.511); catalogued as COSV52703573, COSV52705631; called by muse, mutect2, varscan2
- FAM9A | c.743_745del p.E248del | In Frame Del (DEL) | VAF 16/71 reads (23%) | catalogued as rs755124434; called by pindel, varscan2
- FCGR3A | c.392G>A p.W131* | Nonsense Mutation (SNP) | VAF 50/504 reads (10%) | catalogued as COSV100914693; called by muse, mutect2
- IFIH1 | c.556C>G p.R186G | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.201); catalogued as COSV55125996; called by muse, mutect2, varscan2
- IRF3 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 160/233 reads (69%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.879); catalogued as rs1477763512; called by muse, varscan2
- IRX3 | c.474del p.E159Rfs*11 | Frame Shift Del (DEL) | VAF 73/255 reads (29%) | catalogued as COSV61668777; called by mutect2, pindel*, varscan2
- KDR | c.2731C>T p.P911S | Missense Mutation (SNP) | VAF 50/296 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs764912489; called by muse, mutect2, varscan2
- KMT2A | c.2762T>C p.V921A | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs540438266; called by muse, mutect2, varscan2
- LRPPRC | c.3310G>A p.D1104N | Missense Mutation (SNP) | VAF 57/240 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.289); catalogued as rs147784823, COSV53243859; called by muse, mutect2, varscan2
- MBOAT7 | c.1109C>G p.P370R | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55475584; called by muse, mutect2, varscan2
- MED12L | c.446A>G p.Y149C | Missense Mutation (SNP) | VAF 44/320 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99855283; called by muse, mutect2, varscan2
- MMP13 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 46/290 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52824138, COSV52824346; called by muse, mutect2, varscan2
- MSH2 | c.1510G>C p.G504R | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs63751600, CS011053; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTRF1 | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 6/44 reads (14%) | catalogued as rs759343910; called by mutect2, varscan2
- NALCN | c.5T>A p.L2H | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs754615208; called by muse, mutect2, varscan2
- NEFM | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.124); catalogued as rs778764312, COSV55334427; called by muse, mutect2, varscan2
- NRSN1 | c.87C>A p.Y29* | Nonsense Mutation (SNP) | VAF 47/307 reads (15%) | catalogued as COSV65893888; called by muse, mutect2, varscan2
- NWD1 | c.4084G>A p.V1362M | Missense Mutation (SNP) | VAF 85/357 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as rs142675754; called by muse, mutect2, varscan2
- OR5T1 | c.539_541del p.F180del | In Frame Del (DEL) | VAF 146/587 reads (25%) | catalogued as rs1366422035; called by mutect2, pindel, varscan2
- PABPN1 | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.031); catalogued as COSV53729029; called by muse, mutect2
- PCDH12 | c.1333C>G p.Q445E | Missense Mutation (SNP) | VAF 108/560 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99187825; called by muse, varscan2
- PCF11 | c.111C>G p.I37M | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53534018, COSV53537612; called by muse, mutect2, varscan2
- PEX5L | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 21/149 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs188814073; called by muse, mutect2, varscan2
- PGLYRP3 | c.955G>A p.V319M | Missense Mutation (SNP) | VAF 80/252 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); catalogued as rs1451544204; called by muse, mutect2, varscan2
- POPDC2 | c.1019T>C p.I340T | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as COSV51742903; called by muse, mutect2, varscan2
- PTCH1 | c.649G>T p.D217Y | Missense Mutation (SNP) | VAF 104/181 reads (57%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.519); catalogued as rs780378700; called by muse, varscan2
- RAPGEF1 | c.2132-2A>C p.X711_splice | Splice Site (SNP) | VAF 37/225 reads (16%) | catalogued as COSV64697360; called by muse, mutect2, varscan2
- RYR3 | c.8571C>G p.F2857L (on ENST00000389232; = p.F2858L on NM_001036.6) | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV101212757; called by muse, mutect2, varscan2
- SLC38A5 | c.50T>C p.V17A | Missense Mutation (SNP) | VAF 52/243 reads (21%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs994464670; called by muse, mutect2, varscan2
- SLC4A1 | c.909C>A p.S303R | Missense Mutation (SNP) | VAF 86/270 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as COSV52261292; called by muse, mutect2, varscan2
- SPHKAP | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60870233; called by muse, varscan2
- SUCNR1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100751780; called by muse, mutect2
- TAS1R1 | c.19C>G p.R7G | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV60230296; called by muse, mutect2, varscan2
- THAP3 | c.4C>G p.P2A | Missense Mutation (SNP) | VAF 32/165 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.909); catalogued as rs753867014; called by muse, mutect2, varscan2
- TJP1 | c.690G>C p.L230F | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1350101022; called by muse, mutect2, varscan2
- UAP1 | c.1282C>G p.L428V | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as rs749826575; called by muse, mutect2
- WDR19 | c.1126G>T p.V376F | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.188); catalogued as rs1053642158; called by muse, mutect2, varscan2
- ZNF385B | c.337C>G p.R113G | Missense Mutation (SNP) | VAF 92/184 reads (50%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.999); catalogued as COSV100415848; called by muse, mutect2, varscan2
- ZNF444 | c.503G>T p.G168V | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs975034361; called by muse, mutect2, varscan2
- ZNF469 | c.2489C>G p.S830W | Missense Mutation (SNP) | VAF 221/408 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs773878123; called by muse, mutect2, varscan2
- ZNF618 | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 65/218 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.263); catalogued as rs376782708; called by muse, mutect2, varscan2
- ADAM33 | c.1294G>C p.D432H | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTSL3 | c.4657-21_4663del p.X1553_splice | Splice Site (DEL) | VAF 45/199 reads (23%) | called by mutect2, pindel, varscan2
- ADCY3 | c.3220A>G p.M1074V | Missense Mutation (SNP) | VAF 42/230 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRB1 | c.1234del p.W412Gfs*178 | Frame Shift Del (DEL) | VAF 70/692 reads (10%) | called by mutect2, pindel, varscan2
- ADGRG2 | c.307G>C p.V103L (on ENST00000379869 / NM_001079858.3; = p.V100L on NM_005756.4) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- AGRN | c.2871G>C p.Q957H | Missense Mutation (SNP) | VAF 243/1147 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ANKRD63 | c.142C>G p.R48G | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- ANKS1B | c.1508C>A p.T503K | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AP1B1 | c.1942A>C p.T648P | Missense Mutation (SNP) | VAF 54/228 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- APCS | c.157A>T p.T53S | Missense Mutation (SNP) | VAF 95/559 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APOH | c.646G>C p.V216L | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.037); called by muse, varscan2
- APOL5 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 5/18 reads (28%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP32 | c.5892A>T p.R1964S (on ENST00000310343 / NM_001378025.1; = p.R1615S on NM_014715.4) | Missense Mutation (SNP) | VAF 105/359 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ARID3C | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 83/330 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ARID5B | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 97/431 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP9A | c.1189A>G p.T397A | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- BBS7 | c.719-4_723del p.X240_splice | Splice Site (DEL) | VAF 24/207 reads (12%) | called by mutect2, pindel, varscan2
- BEND3 | c.1361A>G p.Y454C | Missense Mutation (SNP) | VAF 58/377 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BIRC6 | c.134C>A p.A45E | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.092); called by muse, mutect2
- C1S | c.1501_1514del p.K501* | Frame Shift Del (DEL) | VAF 116/532 reads (22%) | called by mutect2, pindel, varscan2
- C1orf127 | c.1400C>G p.P467R | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CABIN1 | c.1591_1617+1del | Frame Shift Del (DEL) | VAF 59/393 reads (15%) | called by mutect2, pindel, varscan2
- CADPS | c.1057A>G p.N353D | Missense Mutation (SNP) | VAF 50/302 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- CADPS | c.507G>T p.Q169H | Missense Mutation (SNP) | VAF 74/254 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CAPRIN2 | c.647C>G p.T216S | Missense Mutation (SNP) | VAF 70/430 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- CCDC168 | c.1141T>C p.Y381H | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC50 | c.671A>T p.E224V | Missense Mutation (SNP) | VAF 100/297 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- CDK5RAP2 | c.1859-2A>G p.X620_splice | Splice Site (SNP) | VAF 10/49 reads (20%) | called by mutect2, varscan2
- CFAP65 | c.4441G>A p.D1481N | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CLCA1 | c.2587T>G p.S863A | Missense Mutation (SNP) | VAF 61/233 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CLEC14A | c.1309T>C p.S437P | Missense Mutation (SNP) | VAF 174/494 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by mutect2, varscan2
- COPA | c.2548G>C p.E850Q | Missense Mutation (SNP) | VAF 30/232 reads (13%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- CPS1 | c.1457C>A p.P486H | Missense Mutation (SNP) | VAF 138/728 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, varscan2
- CR1L | c.1229-5_1247del p.X410_splice | Splice Site (DEL) | VAF 70/364 reads (19%) | called by mutect2, pindel, varscan2
- DAB2 | c.1595T>A p.M532K | Missense Mutation (SNP) | VAF 106/546 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- DIDO1 | c.3362G>A p.R1121H | Missense Mutation (SNP) | VAF 157/361 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DIP2C | c.840C>G p.D280E | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- DNAH1 | c.4093T>C p.F1365L | Missense Mutation (SNP) | VAF 88/278 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- EIF2S3B | c.1355C>G p.P452R | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- EMC1 | c.1553_1558del p.N518_E519del | In Frame Del (DEL) | VAF 36/112 reads (32%) | called by mutect2, pindel, varscan2
- EML1 | c.2075G>T p.G692V | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); called by mutect2, varscan2
- EPHB1 | c.1219C>A p.Q407K | Missense Mutation (SNP) | VAF 94/502 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- EPPK1 | c.2491G>T p.V831F | Missense Mutation (SNP) | VAF 256/1114 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, varscan2
- FAM135B | c.2729A>G p.D910G | Missense Mutation (SNP) | VAF 156/918 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- FAM199X | c.1041G>C p.K347N | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- FAM217B | c.152G>C p.S51T | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FBLN1 | c.981C>A p.N327K | Missense Mutation (SNP) | VAF 70/299 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- FBXL3 | c.746A>G p.H249R | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.702); called by muse, varscan2
- FGD5 | c.2525G>A p.S842N | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- FLT3LG | c.*19C>A | Splice Region (SNP) | VAF 45/226 reads (20%) | called by muse, mutect2, varscan2
- FOLH1 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- FSD1L | c.1474T>G p.C492G | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- GCC2 | c.2276T>G p.L759W | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GIT2 | c.640G>T p.E214* | Nonsense Mutation (SNP) | VAF 18/114 reads (16%) | called by muse, mutect2, varscan2
- GOLGA1 | c.1660A>T p.T554S | Missense Mutation (SNP) | VAF 60/93 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRPEL2 | c.587C>G p.A196G | Missense Mutation (SNP) | VAF 49/232 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- HERC1 | c.12295_12310del p.E4099Lfs*77 | Frame Shift Del (DEL) | VAF 14/71 reads (20%) | called by mutect2, pindel, varscan2
- HMCN1 | c.12636G>C p.L4212F | Missense Mutation (SNP) | VAF 67/398 reads (17%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HOXA5 | c.331G>C p.G111R | Missense Mutation (SNP) | VAF 59/347 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- HSPA6 | c.292A>T p.S98C | Missense Mutation (SNP) | VAF 155/1004 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.774); called by muse, varscan2
- IGF2BP2 | c.1_13del p.M1_?5 | Frame Shift Del (DEL) | VAF 31/143 reads (22%) | called by mutect2, pindel, varscan2
- ITIH5 | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 110/410 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.543); called by muse, mutect2
- ITPK1 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 47/279 reads (17%) | called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.1983G>C p.Q661H | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- JPH3 | c.1147A>T p.I383F | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- KALRN | c.1653G>C p.W551C | Missense Mutation (SNP) | VAF 88/532 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNH1 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 37/195 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRTAP24-1 | c.599C>A p.P200H | Missense Mutation (SNP) | VAF 212/483 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- LAMA3 | c.1559G>A p.C520Y | Missense Mutation (SNP) | VAF 66/648 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LAMA5 | c.2938_2952del p.V980_G984del | In Frame Del (DEL) | VAF 28/274 reads (10%) | called by mutect2, pindel
- LGALS14 | c.311T>C p.V104A | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- LPCAT1 | c.1387A>T p.I463F | Missense Mutation (SNP) | VAF 36/219 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- LZTS1 | c.1303G>C p.D435H | Missense Mutation (SNP) | VAF 67/186 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MADD | c.4206G>T p.K1402N | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- MAGEB3 | c.878C>A p.A293D | Missense Mutation (SNP) | VAF 73/234 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MARCHF11 | c.440G>A p.S147N | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MKS1 | c.484G>A p.V162I | Missense Mutation (SNP) | VAF 66/231 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- MRE11 | c.886A>G p.M296V | Missense Mutation (SNP) | VAF 83/302 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- MRPL22 | c.435G>C p.Q145H | Missense Mutation (SNP) | VAF 60/221 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MTFMT | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0.041); called by muse, mutect2
- MYBPH | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 46/399 reads (12%) | called by muse, mutect2, varscan2
- MYH13 | c.1540G>A p.D514N | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NBEAL1 | c.285del p.K95Nfs*28 | Frame Shift Del (DEL) | VAF 28/148 reads (19%) | called by mutect2, pindel, varscan2
- NCOA6 | c.1531A>G p.M511V | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- NEFL | c.1564G>C p.E522Q | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- NIP7 | c.388G>T p.G130C | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NKAIN1 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NKIRAS2 | c.184A>G p.T62A | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NOP53 | c.608_612del p.D203Afs*7 | Frame Shift Del (DEL) | VAF 30/132 reads (23%) | called by mutect2, pindel, varscan2
- NOTCH2 | c.4522T>C p.Y1508H | Missense Mutation (SNP) | VAF 60/433 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR10J5 | c.517G>T p.V173L | Missense Mutation (SNP) | VAF 185/675 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- OR2B3 | c.926T>C p.F309S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.486); called by muse, mutect2
- OR2S2 | c.845C>A p.P282H | Missense Mutation (SNP) | VAF 30/398 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2
- OR5H2 | c.12G>C p.E4D | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.058); called by muse, mutect2
- P2RY13 | c.298A>G p.I100V | Missense Mutation (SNP) | VAF 156/566 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- PAH | c.11C>A p.A4E | Missense Mutation (SNP) | VAF 100/468 reads (21%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PCDHA11 | c.114G>T p.E38D | Missense Mutation (SNP) | VAF 75/321 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PCNX3 | c.5507_5525del p.D1836Gfs*5 | Frame Shift Del (DEL) | VAF 54/391 reads (14%) | called by pindel, varscan2
- PDZRN4 | c.1207G>A p.V403I (on ENST00000402685 / NM_001164595.2; = p.V145I on NM_013377.4) | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- PHF14 | c.546del p.K182Nfs*19 | Frame Shift Del (DEL) | VAF 55/196 reads (28%) | called by mutect2, pindel, varscan2
- PHOX2B | c.241+4A>C | Splice Region (SNP) | VAF 33/352 reads (9%) | called by muse, mutect2
- PIGL | c.362A>T p.Q121L | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by mutect2, varscan2
- PIWIL3 | c.1861A>G p.T621A | Missense Mutation (SNP) | VAF 79/155 reads (51%) | SIFT tolerated (0.53); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- PLEC | c.13468C>G p.Q4490E (on ENST00000322810 / NM_201380.4; = p.Q4380E on NM_000445.5) | Missense Mutation (SNP) | VAF 179/819 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- PLXND1 | c.5587-6T>C | Splice Region (SNP) | VAF 32/386 reads (8%) | called by muse, mutect2
- POP4 | c.413C>T p.A138V | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PPP6R2 | c.2354G>T p.S785I (on ENST00000216061 / NM_001365836.1; = p.S758I on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRPF6 | c.72-2A>G p.X24_splice | Splice Site (SNP) | VAF 69/324 reads (21%) | called by muse, mutect2, varscan2
- PRRT2 | c.725G>C p.S242T | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- RALGPS1 | c.1036A>C p.N346H | Missense Mutation (SNP) | VAF 73/326 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- RBBP8 | c.1291G>C p.D431H | Missense Mutation (SNP) | VAF 14/153 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2
- RBM48 | c.151C>G p.Q51E | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RFX7 | c.2474G>C p.G825A (on ENST00000559447 / NM_001368074.1; = p.G922A on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- RNF13 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2
- RNF6 | c.322G>C p.D108H | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- RPGRIP1 | c.850C>A p.H284N | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- RPRD2 | c.4041G>T p.R1347S | Missense Mutation (SNP) | VAF 61/405 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- RPS11 | c.91G>C p.E31Q | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SCTR | c.129C>G p.D43E | Missense Mutation (SNP) | VAF 31/256 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SDE2 | c.477G>C p.Q159H | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by mutect2, varscan2
- SELE | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 28/155 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SETD2 | c.3583C>G p.P1195A | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- SHROOM1 | c.2177_2184del p.V726Gfs*12 | Frame Shift Del (DEL) | VAF 64/240 reads (27%) | called by mutect2, pindel, varscan2
- SLC22A16 | c.95T>A p.I32N | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- SLC66A1 | c.453_482del p.A152_A161del | In Frame Del (DEL) | VAF 32/182 reads (18%) | called by mutect2, pindel
- SLC6A19 | c.1602_1620del p.W534Cfs*4 | Frame Shift Del (DEL) | VAF 143/826 reads (17%) | called by mutect2, pindel, varscan2
- SND1 | c.376T>C p.S126P | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- SP2 | c.873_913del p.G292Pfs*43 | Frame Shift Del (DEL) | VAF 52/244 reads (21%) | called by mutect2, pindel, varscan2
- SPACA9 | c.45C>A p.Y15* | Nonsense Mutation (SNP) | VAF 32/271 reads (12%) | called by muse, mutect2, varscan2
- SSH3 | c.1614G>T p.M538I | Missense Mutation (SNP) | VAF 45/368 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- TBR1 | c.1553C>A p.A518E | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- TCHH | c.2635G>C p.E879Q | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.092); called by muse, mutect2
- TENM2 | c.818A>G p.N273S (on ENST00000518659 / NM_001122679.2; = p.N82S on NM_001080428.3) | Missense Mutation (SNP) | VAF 134/583 reads (23%) | SIFT tolerated, low confidence (0.63); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TENM4 | c.3256T>G p.F1086V | Missense Mutation (SNP) | VAF 145/395 reads (37%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- TFAP2A | c.220C>T p.P74S (on ENST00000482890; = p.P66S on NM_001032280.3) | Missense Mutation (SNP) | VAF 61/248 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TG | c.7912C>A p.P2638T | Missense Mutation (SNP) | VAF 45/798 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.444); called by muse, mutect2
- TLR9 | c.2215A>G p.T739A | Missense Mutation (SNP) | VAF 92/226 reads (41%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAF7 | c.364G>C p.A122P | Missense Mutation (SNP) | VAF 63/217 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- TTC38 | c.1317G>C p.R439= | Splice Region (SNP) | VAF 51/142 reads (36%) | called by muse, mutect2, varscan2
- ULK1 | c.1373+2T>G p.X458_splice | Splice Site (SNP) | VAF 27/119 reads (23%) | called by muse, mutect2, varscan2
- VAV1 | c.1060_1061delinsT p.E354* | Frame Shift Del (DEL) | VAF 31/103 reads (30%) | called by pindel, varscan2*
- WDR72 | c.2627C>T p.A876V | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.073); called by mutect2, varscan2
- WDR92 | c.397G>C p.V133L | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- WIZ | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- ZNF41 | c.1793_1798delinsTC p.Q598Lfs*81 | Frame Shift Del (DEL) | VAF 59/250 reads (24%) | called by pindel, varscan2*
- ZNF575 | c.371G>C p.C124S | Missense Mutation (SNP) | VAF 134/218 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by mutect2, varscan2
- ZP3 | c.1097T>C p.I366T (on ENST00000394857 / NM_001110354.2; = p.I315T on NM_007155.6) | Missense Mutation (SNP) | VAF 22/644 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2
- BCL9L | c.3159C>A p.S1053= | Silent (SNP) | VAF 22/90 reads (24%) | called by muse, mutect2, varscan2
- C10orf71 | c.2880T>C p.S960= | Silent (SNP) | VAF 66/271 reads (24%) | called by muse, mutect2, varscan2
- C11orf95 | c.1347C>G p.L449= | Silent (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- C6orf118 | c.1278T>C p.T426= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs759221879; called by muse, mutect2, varscan2
- CACNA1G | c.6732G>A p.K2244= | Silent (SNP) | VAF 52/173 reads (30%) | catalogued as COSV61731879; called by muse, mutect2, varscan2
- CARMIL1 | c.429G>C p.A143= | Silent (SNP) | VAF 19/80 reads (24%) | called by muse, mutect2, varscan2
- CIP2A | c.2067T>C p.L689= | Silent (SNP) | VAF 12/86 reads (14%) | called by muse, mutect2, varscan2
- COL11A1 | c.2748T>C p.G916= | Silent (SNP) | VAF 35/215 reads (16%) | called by muse, mutect2, varscan2
- COL26A1 | c.1017A>C p.T339= (on ENST00000313669 / NM_001278563.3; = p.T337= on NM_133457.4) | Silent (SNP) | VAF 30/207 reads (14%) | called by muse, mutect2
- CRTC3 | c.1818G>A p.L606= | Silent (SNP) | VAF 216/379 reads (57%) | catalogued as rs748760182; called by muse, mutect2, varscan2
- DCC | c.3513T>C p.T1171= | Silent (SNP) | VAF 60/137 reads (44%) | called by muse, mutect2, varscan2
- DENND3 | c.450G>A p.A150= | Silent (SNP) | VAF 20/181 reads (11%) | catalogued as rs267601799, COSV99371076; called by muse, mutect2, varscan2
- EFCAB3 | c.123A>G p.E41= | Silent (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2
- FILIP1L | c.285T>G p.A95= | Silent (SNP) | VAF 23/142 reads (16%) | catalogued as COSV58772484; called by muse, mutect2, varscan2
- GALNT5 | c.1851C>T p.I617= | Silent (SNP) | VAF 66/104 reads (63%) | catalogued as rs1228239748, COSV52036650; called by muse, mutect2, varscan2
- GRIK1 | c.1629C>T p.D543= | Silent (SNP) | VAF 70/192 reads (36%) | called by mutect2, varscan2
- HFE | c.444C>T p.F148= | Silent (SNP) | VAF 82/568 reads (14%) | called by muse, mutect2, varscan2
- HHLA2 | c.646C>T p.L216= | Silent (SNP) | VAF 55/248 reads (22%) | called by muse, mutect2, varscan2
- HSPA6 | c.291G>A p.V97= | Silent (SNP) | VAF 154/996 reads (15%) | catalogued as rs760404533; called by muse, varscan2
- IGKV3D-7 | c.297C>A p.I99= | Silent (SNP) | VAF 56/514 reads (11%) | called by muse, varscan2
- KRT9 | c.1401C>T p.S467= | Silent (SNP) | VAF 33/116 reads (28%) | catalogued as rs946469774, COSV55853509; called by muse, mutect2, varscan2
- LILRA4 | c.285A>T p.R95= | Silent (SNP) | VAF 70/338 reads (21%) | called by muse, mutect2, varscan2
- MBL2 | c.615C>T p.Y205= | Silent (SNP) | VAF 62/366 reads (17%) | called by muse, mutect2, varscan2
- MICALL2 | c.1095C>G p.P365= | Silent (SNP) | VAF 33/80 reads (41%) | called by muse, mutect2, varscan2
- MTCL1 | c.2511C>T p.S837= (on ENST00000306329 / NM_001378206.1; = p.S477= on NM_015210.4) | Silent (SNP) | VAF 84/207 reads (41%) | called by muse, mutect2, varscan2
- MYH6 | c.3375G>A p.E1125= | Silent (SNP) | VAF 148/695 reads (21%) | called by muse, mutect2, varscan2
- MYO3B | c.2160C>A p.I720= | Silent (SNP) | VAF 47/179 reads (26%) | called by muse, mutect2, varscan2
- NLGN4X | c.501C>A p.P167= | Silent (SNP) | VAF 16/76 reads (21%) | called by muse, mutect2, varscan2
- NMS | c.24C>T p.F8= | Silent (SNP) | VAF 50/239 reads (21%) | called by muse, mutect2, varscan2
- NTN5 | c.771G>T p.G257= | Silent (SNP) | VAF 45/98 reads (46%) | called by muse, mutect2, varscan2
- OR2T34 | c.612G>A p.T204= | Silent (SNP) | VAF 88/822 reads (11%) | catalogued as rs534704167; called by muse, mutect2, varscan2
- OR4C3 | c.234A>G p.K78= | Silent (SNP) | VAF 132/705 reads (19%) | called by muse, mutect2, varscan2
- OR4F15 | c.864A>G p.T288= | Silent (SNP) | VAF 49/210 reads (23%) | catalogued as rs750237884; called by muse, mutect2, varscan2
- OTULINL | c.561T>A p.P187= | Silent (SNP) | VAF 15/134 reads (11%) | called by muse, mutect2, varscan2
- OVOL1 | c.330G>T p.G110= | Silent (SNP) | VAF 48/231 reads (21%) | called by muse, mutect2, varscan2
- PCDHGA4 | c.1836C>T p.S612= | Silent (SNP) | VAF 141/641 reads (22%) | catalogued as rs374189449, COSV99533247; called by muse, mutect2, varscan2
- PKHD1 | c.1656T>A p.L552= | Silent (SNP) | VAF 82/430 reads (19%) | called by muse, mutect2, varscan2
- PLAAT5 | c.69C>G p.P23= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as rs1375176583; called by muse, mutect2, varscan2
- POTEE | c.3099C>G p.P1033= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as rs1306169863; called by mutect2, varscan2
- POTEF | c.3099C>G p.P1033= | Silent (SNP) | VAF 212/848 reads (25%) | catalogued as rs1448345079; called by muse, varscan2
- PRR19 | c.354A>T p.P118= | Silent (SNP) | VAF 148/255 reads (58%) | called by muse, mutect2, varscan2
- PSME4 | c.1029T>A p.P343= | Silent (SNP) | VAF 18/119 reads (15%) | called by muse, mutect2, varscan2
- SLC17A7 | c.846G>A p.A282= | Silent (SNP) | VAF 37/230 reads (16%) | catalogued as COSV55547235; called by muse, mutect2, varscan2
- SLC24A4 | c.984C>A p.I328= | Silent (SNP) | VAF 15/257 reads (6%) | called by muse, mutect2
- SLC28A1 | c.1896A>T p.P632= | Silent (SNP) | VAF 297/613 reads (48%) | called by muse, mutect2, varscan2
- SLC37A1 | c.369C>T p.R123= | Silent (SNP) | VAF 22/112 reads (20%) | called by muse, mutect2, varscan2
- SOX14 | c.624T>G p.S208= | Silent (SNP) | VAF 81/625 reads (13%) | called by muse, mutect2, varscan2
- SPPL2B | c.927G>C p.V309= | Silent (SNP) | VAF 60/114 reads (53%) | called by muse, mutect2, varscan2
- TRAK1 | c.2355G>A p.S785= | Silent (SNP) | VAF 134/643 reads (21%) | catalogued as rs746326356; called by muse, mutect2, varscan2
- YY1AP1 | c.2113T>C p.L705= (on ENST00000295566 / NM_139118.2; = p.L648= on NM_018253.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 157/911 reads (17%) | called by muse, mutect2, varscan2
- ZNF117 | c.825G>A p.K275= | Silent (SNP) | VAF 19/143 reads (13%) | catalogued as rs878931045; called by muse, mutect2, varscan2
- ZNF512B | c.1440C>A p.V480= | Silent (SNP) | VAF 37/154 reads (24%) | catalogued as COSV99412157; called by muse, mutect2, varscan2
- ADAM6 | n.679G>T | RNA (SNP) | VAF 96/424 reads (23%) | called by muse, mutect2, varscan2
- AIF1 | c.196+18T>G | Intron (SNP) | VAF 21/78 reads (27%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824034 del TTGTGCCCCCAG | 5'Flank (DEL) | VAF 48/149 reads (32%) | called by mutect2, pindel, varscan2
- BAIAP2 | chr17:81031050 C>G | 5'Flank (SNP) | VAF 85/402 reads (21%) | called by muse, mutect2, varscan2
- C1orf141 | c.346+1600C>G | Intron (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- CACNB4 | c.-1G>C | 5'UTR (SNP) | VAF 7/25 reads (28%) | catalogued as COSV104389842; called by muse, mutect2
- CARNS1 | c.-367+483G>C | Intron (SNP) | VAF 40/205 reads (20%) | called by muse, mutect2, varscan2
- CSH1 | c.457-73A>G | Intron (SNP) | VAF 175/561 reads (31%) | called by muse, mutect2, varscan2
- ECT2 | c.2656-1560C>G | Intron (SNP) | VAF 20/144 reads (14%) | called by muse, mutect2, varscan2
- ERVV-1 | chr19:53010152 C>G | 5'Flank (SNP) | VAF 143/258 reads (55%) | called by muse, mutect2, varscan2
- FGF23 | c.*51T>C | 3'UTR (SNP) | VAF 62/206 reads (30%) | called by muse, mutect2, varscan2
- FTH1 | c.-59C>T | 5'UTR (SNP) | VAF 43/234 reads (18%) | called by muse, mutect2, varscan2
- GALNT14 | c.129+59010G>A | Intron (SNP) | VAF 23/187 reads (12%) | called by muse, mutect2, varscan2
- GPR107 | chr9:130141664 G>T | 3'Flank (SNP) | VAF 73/173 reads (42%) | called by muse, mutect2, varscan2
- GRIA4 | c.487+44594C>T | Intron (SNP) | VAF 34/197 reads (17%) | catalogued as rs1467312975; called by muse, mutect2, varscan2
- GRIPAP1 | c.-15G>T | 5'UTR (SNP) | VAF 19/62 reads (31%) | catalogued as rs782775662; called by muse, mutect2, varscan2
- ITFG2 | c.193-12_193-10del | Intron (DEL) | VAF 25/94 reads (27%) | called by mutect2, pindel, varscan2
- MFRP | chr11:119343858 A>G | 5'Flank (SNP) | VAF 176/830 reads (21%) | catalogued as rs750567143; called by muse, mutect2, varscan2
- NDRG1 | c.855+15G>T | Intron (SNP) | VAF 28/367 reads (8%) | called by muse, mutect2
- NFASC | c.2470+2106A>G | Intron (SNP) | VAF 52/238 reads (22%) | called by muse, varscan2
- NKD2 | c.331-42G>T | Intron (SNP) | VAF 68/192 reads (35%) | catalogued as rs780254069; called by muse, mutect2, varscan2
- NUDT16L1 | c.414+154G>C | Intron (SNP) | VAF 25/66 reads (38%) | catalogued as rs1202400826; called by muse, mutect2, varscan2
- PCBP4 | c.139-33C>T | Intron (SNP) | VAF 53/316 reads (17%) | catalogued as rs1559760268; called by muse, mutect2, varscan2
- PGC | c.648-395C>A | Intron (SNP) | VAF 36/152 reads (24%) | called by muse, mutect2, varscan2
- PSTPIP1 | c.838+118A>C | Intron (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2
- RAB17 | c.435+669C>T | Intron (SNP) | VAF 39/138 reads (28%) | catalogued as rs1027397968; called by muse, mutect2, varscan2
- RBFOX3 | c.756-112C>A | Intron (SNP) | VAF 26/93 reads (28%) | called by muse, mutect2, varscan2
- RBM34 | chr1:235161320 del CGGCAGTCGGCCGCCGGG | 5'Flank (DEL) | VAF 11/76 reads (14%) | called by mutect2, pindel, varscan2
- RBM44 | c.-98-2721G>C | Intron (SNP) | VAF 52/123 reads (42%) | called by muse, mutect2, varscan2
- SH3YL1 | c.781+9T>A | Intron (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- SLC6A19 | c.1017-27G>T | Intron (SNP) | VAF 167/837 reads (20%) | called by muse, mutect2, varscan2
- SSPOP | n.13927T>C | RNA (SNP) | VAF 111/478 reads (23%) | called by muse, mutect2, varscan2
- TIA1 | c.311-585A>T | Intron (SNP) | VAF 10/63 reads (16%) | called by muse, mutect2, varscan2
- TMEM52 | c.171-83C>T | Intron (SNP) | VAF 74/485 reads (15%) | catalogued as rs771657553; called by muse, mutect2, varscan2
- UBE2C | c.217-59G>T | Intron (SNP) | VAF 40/249 reads (16%) | called by muse, mutect2, varscan2
- YAF2 | c.153-37411C>G | Intron (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
- ZEB2 | c.73+4861G>A | Intron (SNP) | VAF 29/219 reads (13%) | catalogued as rs1366345017; called by muse, mutect2, varscan2
- ZEB2 | chr2:144520068 G>C | 5'Flank (SNP) | VAF 47/167 reads (28%) | called by muse, mutect2, varscan2
